TCGA case TCGA-5L-AAT1 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: University of Sao Paulo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16fc3677-0393-4ed1-ad3f-c8355f056369

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Brazil; Age at index: 63 years; Vital status: Alive.

Diagnoses (2)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 63.6 years (23,225 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1; Micrometastasis present: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Days to treatment start: 46 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 52.9 years (19,339 days); Days to diagnosis: -3,886 days (-10.6 years); AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -3,890 days (-10.7 years); Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -3,871 days (-10.6 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Days to treatment start: -3,779 days (-10.3 years); Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 1,471 days (4.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ESR1 (IHC): Positive; Test value range: 80-89%.
- PGR (IHC): Positive; Test value range: 10-19%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5L-AAT1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 130 mg.
  Slide TCGA-5L-AAT1-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 35; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-5L-AAT1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-5L-AAT1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Axillary staging method other: Level 1 clearance; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Her2 IHC score: 2+; Margin status: Negative; Method initial path diagnosis: Tumor resection; Her2 positivity scale other: Cish; Her2 positivity method text: Cish; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- First nonlymph node metastasis anatomic sites: Metastasis site: Bone.
- Drug treatment: Pharmaceutical therapy drug name: Letrozol.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Tubulo-lobular invasive carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Modified Radical Mastectomy.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had prior breast malignancy (in opposite breast) with systemic chemotherapy (Tamoxifen).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,471 days; disease-specific survival: no event (censored), 1,471 days; progression-free interval: no event (censored), 1,471 days.
